FM case AD7015 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts.
https://portal.gdc.cancer.gov/cases/889f7123-1213-4c35-80f0-7d04fc674db1

Female, 61.6 years: Hepatocellular carcinoma, NOS (ICD-O-3 8170/3) of the liver; primary biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
